Somatic mutation profile of tumor specimen TARGET-10-PARDMI-09A (aliquot TARGET-10-PARDMI-09A-01D) from TARGET case TARGET-10-PARDMI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,529 days).
Specimen TARGET-10-PARDMI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94b72233-bcc5-43ad-8789-ff9683493ee6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDMI-10A (Blood Derived Normal), aliquot TARGET-10-PARDMI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fdee6a0-5009-4504-8c00-3eefc382a7fd

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 4, Silent 3, Frame Shift Ins 2, 3'UTR 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.1797C>G p.I599M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV55002503; called by muse, mutect2, varscan2
- ADGRG4 | c.7362G>T p.K2454N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV54953404; called by muse, mutect2, varscan2
- CCDC157 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs748207336; called by muse, mutect2, varscan2
- CFAP74 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1194089261; called by muse, mutect2
- IQGAP2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs778649304, COSV57174320; called by muse, mutect2, varscan2
- NUP153 | c.2681C>G p.S894C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs746217374; called by mutect2, varscan2
- RGS14 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1175411425; called by muse, mutect2
- SYNE1 | c.2474C>T p.T825M (on ENST00000367255 / NM_182961.4; = p.T832M on NM_033071.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs777634676, COSV99558953; called by muse, mutect2, varscan2
- THEMIS | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747611832; called by muse, mutect2, varscan2
- TTLL6 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100938192; called by muse, mutect2
- ABRAXAS2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD26 | c.4069G>C p.E1357Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ATP11C | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC168 | c.4220T>A p.V1407E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CXCR4 | c.1000_1001insCCCCGCGCCATGCGCC p.R334Pfs*15 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel
- EXPH5 | c.4355G>A p.R1452K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JRKL | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAX5 | c.641_642insCCTTGGGGATAATCGCT p.P215Lfs*69 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- SNUPN | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- UBA2 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UST | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- DNAH1 | c.9216G>A p.R3072= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- KCTD15 | c.549C>G p.L183= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.165G>A p.G55= | Silent (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3365G>A | Intron (SNP) | VAF 47/151 reads (31%) | catalogued as rs1393729460; called by muse, mutect2, varscan2
- CCDC69 | c.*112G>A | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- CCDC89 | chr11:85682835 G>A | 3'Flank (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- NECTIN2 | c.1043-3722G>C | Intron (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- NGB | c.*12G>A | 3'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as rs968725170; called by muse, mutect2, varscan2
- TEX9 | c.28-23G>A | Intron (SNP) | VAF 28/100 reads (28%) | catalogued as COSV100771558; called by muse, mutect2, varscan2
- TMEM131L | c.4414+13C>G | Intron (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
